Somatic mutation profile of tumor specimen C3L-01052-02 (aliquot CPT0123750006_1) from CPTAC case C3L-01052, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 64.9 years (23,696 days).
Specimen C3L-01052-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f3122ce-017d-4254-9606-e1720239c792.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01052-31 (Blood Derived Normal), aliquot CPT0124880002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d3f12593-8ce8-4f26-ab7d-42402db1103c

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGF8 | c.323C>T p.T108M (on ENST00000344255 / NM_033164.4; = p.T90M on NM_006119.6) | Missense Mutation (SNP) | VAF 24/946 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876661329, COSV60143748; ClinVar: likely pathogenic; called by muse, mutect2
- PCDHA3 | c.1705C>T p.R569W | Missense Mutation (SNP) | VAF 27/1100 reads (2%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as rs782553261, COSV100793868; called by muse, mutect2
- MUC12 | c.8042G>A p.S2681N (on ENST00000379442; = p.S2538N on NM_001164462.1) | Missense Mutation (SNP) | VAF 26/1367 reads (2%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.591); called by muse, mutect2
- DDX42 | c.1066C>A p.R356= | Silent (SNP) | VAF 22/563 reads (4%) | catalogued as COSV63790195; called by muse, mutect2
